Surgical pathology report (de-identified scan), TCGA case TCGA-HZ-8638, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-HZ-8638-01A (Primary Tumor).

[page 1 of 5]
FINAL SURGICAL PATHOLOGY REPORT

Diagnosis:

A. & B.) PANCREAS, TOTAL PANCREATECTOMY (INCLUDES PORTION OF DUODENUM AND DISTAL STOMACH):

- SMALL FOCUS OF INVASIVE MUCINOUS ADENOCARCINOMA (APPROXIMATELY 0.3 CM IN DIAMETER) PRESENT IN ASSOCIATION WITH INTRADUCTAL PAPILLARY MUCINOUS NEOPLASM (IPMN).
- AREAS OF HIGH-GRADE DYSPLASIA WITHIN IPMN, MAIN PANCREATIC DUCT, COMMON BILE DUCT.
- THE FINAL COMMON BILE DUCT MARGIN IS FREE OF HIGH-GRADE DYSPLASIA.
- TWELVE BENIGN PERIPANCREATIC LYMPH NODES (0/12).
- RESECTION MARGINS ARE FREE OF TUMOR.

COMMENT: The specimen was thoroughly sampled, including the entire area of grossly identifiable lesion in the head of the pancreas. This area represents intraductal papillary mucinous neoplasm, which has varying degrees of dysplasia ranging from mild to severe. Within the area of IPMN, a 0.3 cm focus of invasive (mucinous) carcinoma is identified. Dysplasia is also identified in pancreatic ducts in the tail of the pancreas. Intradepartmental consultation: [REDACTED] has reviewed representative slides, and concurs with the above diagnosis.

Tumor Staging Information

Data derived from current specimen. Staging in accordance with or modified from AJCC Cancer Staging Handbook, [REDACTED] and CAP protocol, [REDACTED]

[page 2 of 5]
Specimen:

Total pancreatectomy with portion of stomach and duodenum.

Tumor features:

Tumor site:

Head of pancreas.

Tumor size:

Invasive tumor size 0.3 cm in diameter.

Size of IPMN: 4.2 cm in diameter.

Histologic type:

Mucinous adenocarcinoma, arising in a background of IPMN.

Histologic grade:

Intermediate to high nuclear grade.

Microscopic tumor extension:

Tumor is confined to the pancreas.

Margins:

Margins uninvolved by invasive carcinoma and IPMN.

Lymph-vascular invasion:

Not identified.

Perineural invasion:

Not identified.

Lymph nodes examined:

Twelve.

Lymph nodes involved:

Zero.

PATHOLOGIC TUMOR STAGING:

Primary tumor:

pT1.

Regional lymph nodes:

pN0.

Distant metastasis:

Not applicable.

AJCC Stage:

IA

[page 3 of 5]
FINAL SURGICAL PATHOLOGY REPORT

Source of Specimen:

- A. Total pancreatectomy
- B. Bile duct

Clinical History/Operative Dx:

Pancreatic carcinoma

Intraoperative Diagnosis:

A. FSA: Pancreas: Bile duct margin with severe dysplasia. [REDACTED]

The intraoperative interpretation(s) was/were performed and rendered at [REDACTED]
[REDACTED]

B. FSB: New bile duct margin: New margin free of dysplasia.

Gross Description:

A. Part A designated total pancreatectomy, string marks the bile duct. Initially received in a fresh state for frozen section analysis is a generous portion of tissue, consistent with a Whipple procedure specimen. The antrum-pyloric termination of the stomach is 3.2 cm in length and up to 3.0 cm in diameter, the small bowel is 20.5 cm x 2.7 cm, and the total pancreatectomy is 18.0 cm in length with a diameter range of 1.5 x 1.5 x 2.0 cm distally. The head of the pancreas measures 6.0 cm superior-inferior, and 3.8 cm posterior-anterior. The gastric and small bowel serosa is hyperemic to congested, light pink to dusky red, and the pancreas is light yellow-tan, initially without palpable mass lesion.

The proximal, common bile duct extends out to 1.4 cm and 1.6 cm in diameter, with a patent 0.8 cm lumen. The CBD margin is trimmed and submitted for frozen section analysis. The frozen tissue is submitted for permanent sections. The stomach and small bowel length is now open to reveal the ampulla of Vater positioned 6.8 cm distal to the pylorus and 13.7 cm from the distal small bowel margin of resection. The lumen is 0.5 cm in diameter, the orifice demonstrates a raised granular red in appearance over an area of 2.2 x 1.1 cm and 0.7 cm into the ductal tract. A representative portion of this highly suspicious area is submitted for Oncogenotyping studies. The surface of the pancreas are now differentially inked as follows:

Anterior surface - yellow,
Inferior - green,
Superior - blue,
Posterior - black,
Pancreatic groove - red,
Uncinate - black.

The head of the pancreas and the most length of the pancreas is bisected along the pancreatic duct, and the specimen is pinned out and fixed overnight, to enhance gross examination, dissection, and processing. The pancreatic duct is probe-patent, and merges with the common bile duct, within 1.6 cm of the AV orifice. The remainder of the length of the CBD is opened, demonstrating a delicate, light pink to focally congested, purple-red appearance with sloughing yellow-gray exudate. Within 0.7 cm of the original

[page 4 of 5]
FINAL SURGICAL PATHOLOGY REPORT

CBD surgical margin, the mucosa demonstrates a raised firm dusky red lesion, 0.8 x 0.4 cm. The lesion appears grossly confined. Further examination of the head of the pancreas reveals a well circumscribed, multiloculated cystic, pink-gray mass lesion, 4.2 x 2.3 x 2.0 cm, abutting the anterior, inferior surfaces of the pancreas, including the mesenteric groove/pancreatic notch. The lesion partially encases the pancreatic duct, which is dilated to 0.7 cm and contains mucinous material, similar to the mucin within the multilocular spaces of the mass.

The pancreatic tissue surrounding the mass demonstrates a rubbery to indurated light tan appearance. The length of the pancreas demonstrates a similar glandular appearance, with transient areas of increased induration/firmness, and foci of hemorrhagic congestion. Within 2.0 cm of the tail of the pancreas, the inferior half of the pancreas demonstrates a 2.0 x 1.4 cm hematoma, with the adjacent pancreatic duct demonstrating petechial congestion along 6.0 cm of the length. No additional lesions appreciated.

Examination of the gastric mucosa demonstrates a pylorus with a raised, semi-congested and granular appearance. The length of the duodenum demonstrates prominent, semi-congested, light tan to distally deep red, circular plica, without additional lesion.

Initial examination of the peripancreatic fat reveals twenty-two lymph node candidates ranging from 0.2 cm to 2.6 cm in greatest dimension, rubbery pink and tan. Representative sections are submitted for microscopic evaluation.

Cassette summary:

- A1) common bile duct margin, frozen section,
- A2) additional CBD end,
- A3) lesion near CBD margin/superior pancreas,
- A4) length of CBD, including bifurcation,
- A5-A7) ampulla of Vater and lesion blocked out section and submitted,
- A8-A9) lesion, anterior pancreas,
- A10-A11) lesion, inferior pancreas,
- A12-A13) lesion, pancreatic groove,
- A14-A15) uncinate, four pieces,
- A16-A21) length of pancreas represented, head to tail, eleven pieces,
- A22) gastric margin of resection,
- A23) small bowel distal margin of resection,
- A24) gastric-pylorus sphincter represented,
- A25) small bowel length represented,
- A26) four peripancreatic lymph node candidates,
- A27) six lymph node candidates,
- A28) five lymph node candidates,
- A29) two lymph node candidates,
- A30) single lymph node candidate bisected,
- A31) single lymph node candidate bisected,
- A32) single lymph node candidate sectioned and submitted,
- A33-A34) largest lymph node candidate sectioned and submitted

[page 5 of 5]
FINAL SURGICAL PATHOLOGY REPORT

Upon review of the initial slides, additional representative sections are submitted in A35-A42. [REDACTED]

B. Part B is labeled bile duct. Initially received in the fresh state for frozen section analysis is a tubular, pink and tan fragment of soft tissue measuring 1.2 cm in length and 1.3 cm in diameter. The lumen is 0.7 cm in diameter and the mucosa demonstrates a glistening, light to granular deep red appearance. A suture marks the end designated as "new margin". This end is trimmed and submitted for frozen section analysis with the residual frozen tissue submitted in B1 for permanent sections. The remainder of the specimen is submitted as two pieces in B2, for routine histology [REDACTED]

Microscopic Description:

A. - B.) Immunohistochemical stains: Ki-67, showing varying percentages of dysplastic cells positive for Ki-67 with higher percentages identified in areas of high-grade dysplasia. Appropriate positive and negative controls reviewed.

Source: NCI Genomic Data Commons file 3fd705d5-087e-4004-9695-21475807b9d6 (TCGA-HZ-8638.AB82EAF3-2F55-47AB-819F-9AD1000F7EB1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).